CCDI case PBCLRU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0317cd74-c26d-4ded-8eda-2fc4b570f087

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.4 years (499 days).

Biospecimens (3 samples)
- Sample 0DVCDR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCF5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
